Gene-level copy-number profile of tumor specimen TCGA-AP-A05J-01A from TCGA case TCGA-AP-A05J, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 66.0 years (24,119 days).
Specimen TCGA-AP-A05J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.60dab789-34da-4607-8a20-467b8adc2f7f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A05J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30ef95f0-5b4a-46d0-8c86-4acb46070eeb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,524; copy number 3: 709; copy number 4: 45,771; copy number 5: 840; copy number 6: 2,695; copy number 7: 566; copy number 8: 271; copy number 9: 329; copy number 10: 34; copy number 12: 29; copy number 14: 26; copy number 18: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A05J-01A-11D-A00X-01): tumor purity 0.95, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 428 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:13,316,235–13,880,071, 8 genes, copy number 12 (within-gene range 6–12): NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A.
- chr3:14,089,107–14,394,757, 10 genes, copy number 9: VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124.
- chr3:190,305,707–191,398,659, 15 genes, copy number 9: CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50.
- chr4:1,345,691–2,462,942, 32 genes, copy number 9–12: UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2, COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1, CFAP99.
- chr4:2,463,797–2,506,279, 2 genes, copy number 9: AL645924.1, AL645924.2.
- chr7:1,688,119–1,747,954, 1 gene, copy number 9 (within-gene range 2–9): ELFN1.
- chr7:1,738,630–3,118,049, 27 genes, copy number 9: ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655, MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1.
- chr7:74,289,407–75,074,228, 17 genes, copy number 9–10 (within-gene range 4–10): CLIP2, GTF2IRD1, RNA5SP233, AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2, RCC1L, Metazoa_SRP.
- chr10:120,925,547–122,461,383, 24 genes, copy number 9 (within-gene range 6–9): AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1.
- chr11:1,802,889–2,173,138, 26 genes, copy number 14: AC139143.1, SYT8, TNNI2, LSP1, MIR4298, AC051649.1, MIR7847, PRR33, LINC01150, TNNT3, MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2, IGF2, AC132217.2, AC132217.1, INS-IGF2, MIR483, IGF2-AS, INS, TH, MIR4686.
- chr11:66,848,417–68,130,518, 77 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:87,944,885–95,217,482, 127 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr17:732,412–1,684,867, 34 genes, copy number 9 (within-gene range 4–9): TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1, AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8.
- chr20:32,052,197–32,961,609, 28 genes, copy number 10–18 (within-gene range 4–18): HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
